Gene-level copy-number profile of tumor specimen C3N-00549-03 from CPTAC case C3N-00549, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 58.6 years (21,402 days).
Specimen C3N-00549-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 63fbcde4-90bb-4e4c-aff1-843a741e2644.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00549-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/dc66566a-ea80-4788-a415-85e13de43f40

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 376; copy number 1: 67; copy number 2: 21,516; copy number 3: 8,087; copy number 4: 20,665; copy number 5: 5,392; copy number 6: 2,626; copy number 7: 160; copy number 9: 5; copy number 10: 1; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,878,835–8,894,151, 3 genes (within-gene range 0–2): ENO1-AS1, RNU6-304P, HMGN2P17.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:146,052,604–146,056,762, 1 gene: AC108206.1.
- chr4:177,181,442–177,681,381, 7 genes: RN7SKP136, AC097518.1, NEIL3, AC027627.1, AGA, AC078881.1, RNA5SP172.
- chr5:180,967,189–180,982,611, 3 genes: AC091874.2, AC091874.1, ARPP19P1.
- chr22:18,422,244–18,615,900, 12 genes: FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:1,508,655–1,509,427, 1 gene, copy number 9: AC093734.1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr21:12,999,676–13,016,692, 1 gene, copy number 10: AP001464.1.
- chr21:44,172,169–44,194,338, 2 genes, copy number 12: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
